Somatic mutation profile of tumor specimen C3L-05839-02 (aliquot CPT0346880007) from CPTAC case C3L-05839, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-05839-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ce33f88-2724-481e-920b-0aed1c713390.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05839-32 (Blood Derived Normal), aliquot CPT0347040005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/956e52ac-908b-425a-a065-d171c6082141

The open-access MAF lists 360 somatic variants for this specimen: 231 protein-altering or splice-affecting, 120 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 211, Silent 120, Nonsense Mutation 10, Intron 4, Splice Site 3, Splice Region 3, Frame Shift Del 3, 3'Flank 2, 5'Flank 1, RNA 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPHS2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 147/291 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786204583, CM042094, CM042096, COSV62635309; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV56859084; called by muse, mutect2, varscan2
- ADAMTS12 | c.3775C>T p.P1259S | Missense Mutation (SNP) | VAF 161/456 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV61283633; called by muse, mutect2, varscan2
- ADAMTS13 | c.724T>A p.C242S | Missense Mutation (SNP) | VAF 129/188 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CD035976; called by muse, mutect2, varscan2
- AL645922.1 | c.2242G>A p.D748N | Missense Mutation (SNP) | VAF 392/448 reads (88%) | SIFT tolerated (1); PolyPhen benign (0.227); catalogued as rs1291146038, COSV54962581; called by muse, mutect2, varscan2
- ANKRD2 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 110/168 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs760926039, COSV53968048; called by muse, mutect2, varscan2
- ANKRD50 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 136/317 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs1343809844; called by muse, mutect2, varscan2
- APOB | c.9706G>A p.E3236K | Missense Mutation (SNP) | VAF 80/289 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as rs1422346794; called by muse, mutect2, varscan2
- ATG9A | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as COSV63445350; called by muse, mutect2, varscan2
- BRAF | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 176/332 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267601317, COSV56269245, COSV56448507; called by muse, varscan2
- C1QTNF9B | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 123/822 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65943899; called by muse, mutect2, varscan2
- C1S | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 88/273 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.364); catalogued as COSV61072472; called by muse, mutect2, varscan2
- C3 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 124/301 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs373896614; called by muse, mutect2, varscan2
- C3orf85 | c.48C>T p.I16= | Splice Region (SNP) | VAF 105/295 reads (36%) | catalogued as rs187839586; called by muse, mutect2, varscan2
- CACNA1E | c.4924C>T p.R1642W | Missense Mutation (SNP) | VAF 164/459 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1294061346, COSV100701959; called by muse, mutect2, varscan2
- CACNA1E | c.6812C>T p.P2271L (on ENST00000367573 / NM_001205293.3; = p.P2228L on NM_000721.4) | Missense Mutation (SNP) | VAF 194/572 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV100701183; called by muse, mutect2, varscan2
- CACNA1H | c.1669C>T p.P557S | Missense Mutation (SNP) | VAF 246/601 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1394895640; called by muse, mutect2, varscan2
- CATSPERB | c.1796G>A p.G599E | Missense Mutation (SNP) | VAF 127/368 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.382); catalogued as COSV56437974; called by muse, mutect2, varscan2
- CATSPERB | c.1795G>A p.G599R | Missense Mutation (SNP) | VAF 124/363 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99831578; called by muse, mutect2, varscan2
- CCNA1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 155/359 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55220977; called by muse, mutect2, varscan2
- CHL1 | c.1903G>A p.G635R (on ENST00000397491 / NM_001253387.1; = p.G651R on NM_006614.4) | Missense Mutation (SNP) | VAF 147/324 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1255098135; called by muse, mutect2, varscan2
- COL4A2 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 111/289 reads (38%) | catalogued as rs267603755; called by muse, varscan2
- COL5A2 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 53/233 reads (23%) | catalogued as COSV66412259; called by muse, mutect2, varscan2
- COL5A2 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs749983032; called by muse, mutect2, varscan2
- COQ4 | c.788G>A p.G263D | Missense Mutation (SNP) | VAF 121/177 reads (68%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.147); catalogued as rs1169428477; called by muse, mutect2, varscan2
- CSMD2 | c.7649G>A p.G2550E | Missense Mutation (SNP) | VAF 248/430 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.631); catalogued as COSV53907800; called by muse, mutect2, varscan2
- CYP2C19 | c.690T>A p.H230Q | Missense Mutation (SNP) | VAF 74/112 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV64908313; called by muse, mutect2, varscan2
- CYP2C8 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 63/98 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.07); catalogued as COSV64876187; called by muse, mutect2, varscan2
- CYP3A4 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 65/324 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV100315655; called by muse, mutect2, varscan2
- CYYR1 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 213/278 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100176833; called by muse, mutect2, varscan2
- DCHS1 | c.5373T>C p.D1791= | Splice Region (SNP) | VAF 62/150 reads (41%) | catalogued as rs755278880; called by muse, mutect2, varscan2
- DNAH5 | c.9617G>A p.G3206E | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54209483, COSV99447926; called by muse, mutect2, varscan2
- DNAH7 | c.6424C>T p.P2142S | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.028); catalogued as COSV56757160; called by muse, mutect2, varscan2
- DSPP | c.2659G>A p.E887K | Missense Mutation (SNP) | VAF 207/492 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs1441961526, COSV99217676; called by muse, mutect2, varscan2
- ERC2 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 187/472 reads (40%) | catalogued as COSV55612411; called by muse, mutect2, varscan2
- FAM186B | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 107/305 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.13); catalogued as COSV57721440, COSV99074436; called by muse, mutect2, varscan2
- FARP2 | c.1630C>T p.L544F | Missense Mutation (SNP) | VAF 78/267 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV104382741; called by muse, mutect2, varscan2
- FLRT3 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 93/300 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54028505; called by muse, mutect2, varscan2
- GLRB | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 101/297 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs145671356, COSV52413591; called by muse, mutect2, varscan2
- GPRIN1 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 168/441 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs933585251; called by muse, mutect2, varscan2
- GRM4 | c.827C>T p.S276L | Missense Mutation (SNP) | VAF 353/420 reads (84%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as rs200915496; called by muse, mutect2, varscan2
- HMCN1 | c.6346C>T p.L2116F | Missense Mutation (SNP) | VAF 136/420 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV99634936; called by muse, mutect2, varscan2
- ITPRIP | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 210/296 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs899676080; called by muse, mutect2, varscan2
- KIAA1217 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 218/297 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56815063; called by muse, mutect2, varscan2
- KIF7 | c.2477G>A p.R826Q | Missense Mutation (SNP) | VAF 139/367 reads (38%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.829); catalogued as rs148044329; called by muse, mutect2, varscan2
- KLHL4 | c.181G>A p.G61R | Missense Mutation (SNP) | VAF 194/256 reads (76%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs1371677607; called by muse, mutect2, varscan2
- LAMA5 | c.3244C>T p.P1082S | Missense Mutation (SNP) | VAF 165/455 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as COSV53364307; called by muse, mutect2, varscan2
- LARS1 | c.3127G>A p.E1043K (on ENST00000394434 / NM_020117.11; = p.E1016K on NM_016460.3) | Missense Mutation (SNP) | VAF 107/275 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs368838241; called by muse, mutect2, varscan2
- LBR | c.1534C>T p.R512W | Missense Mutation (SNP) | VAF 152/339 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373561199; called by muse, mutect2, varscan2
- LETM1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 93/271 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs548475002; called by muse, mutect2, varscan2
- LLGL2 | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 211/531 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV51342341; called by muse, mutect2, varscan2
- LMLN2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 114/296 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as rs773065471; called by muse, mutect2, varscan2
- LRBA | c.7543C>T p.P2515S | Missense Mutation (SNP) | VAF 144/353 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as rs866459305; called by muse, mutect2, varscan2
- MAGEC2 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 187/234 reads (80%) | SIFT tolerated (0.5); PolyPhen benign (0.119); catalogued as COSV56001944; called by muse, mutect2, varscan2
- MAGI2 | c.3688G>A p.G1230R | Missense Mutation (SNP) | VAF 205/661 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100833899; called by muse, mutect2, varscan2
- MAP7 | c.418G>A p.E140K | Missense Mutation (SNP) | VAF 108/147 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs373827555; called by muse, mutect2, varscan2
- MCM3 | c.1541T>C p.M514T (on ENST00000229854 / NM_001366374.2; = p.M504T on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 322/383 reads (84%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); catalogued as rs1405571338; called by muse, mutect2, varscan2
- MEFV | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 148/337 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as COSV99560923; called by muse, mutect2, varscan2
- MFSD6L | c.1639C>T p.R547* | Nonsense Mutation (SNP) | VAF 171/467 reads (37%) | catalogued as rs144438269, COSV104395648; called by muse, mutect2, varscan2
- NCKAP1L | c.2504C>T p.S835F | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV53207676; called by muse, mutect2, varscan2
- NFKBIE | c.476T>C p.I159T (on ENST00000275015; = p.I20T on NM_004556.3) | Missense Mutation (SNP) | VAF 458/545 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs1372142398; called by muse, mutect2, varscan2
- NLRP7 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 224/539 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs1240014954; called by muse, mutect2, varscan2
- NOS1 | c.2386T>G p.Y796D | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57607500; called by muse, mutect2, varscan2
- NRXN3 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 157/424 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV101627037; called by muse, mutect2, varscan2
- NXF1 | c.1622C>T p.S541F | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV53674408; called by muse, mutect2, varscan2
- OR10C1 | c.749C>T p.S250F (on ENST00000622521; = p.S248F on NM_013941.3) | Missense Mutation (SNP) | VAF 650/773 reads (84%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); catalogued as COSV65823828; called by muse, mutect2, varscan2
- OR2G2 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 212/413 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV100189754; called by muse, mutect2, varscan2
- OR2G3 | c.166C>T p.H56Y | Missense Mutation (SNP) | VAF 191/375 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV60682245; called by muse, mutect2, varscan2
- OR5D16 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 79/251 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.38); catalogued as rs867879197, COSV65721582; called by muse, mutect2, varscan2
- OR5G3 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.522); catalogued as rs1311302169; called by muse, mutect2, varscan2
- ORAI2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 289/495 reads (58%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1422271642; called by muse, mutect2, varscan2
- PAPSS1 | c.1859C>T p.S620F | Missense Mutation (SNP) | VAF 115/276 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV54491346; called by muse, mutect2, varscan2
- PCDH15 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 165/224 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57311991; called by muse, mutect2, varscan2
- PCDHA1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 202/475 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65372830; called by muse, mutect2, varscan2
- PDCD1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 127/267 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV57692311; called by muse, mutect2, varscan2
- PDE3A | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 132/367 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as rs143792143; called by muse, mutect2, varscan2
- PIGS | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 79/253 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572109106; called by muse, mutect2, varscan2
- PLCD4 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs547899357; called by muse, mutect2, varscan2
- PLCE1 | c.3433C>T p.P1145S | Missense Mutation (SNP) | VAF 193/268 reads (72%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV53364742; called by muse, mutect2, varscan2
- PPFIA4 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 138/374 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV55320716; called by muse, mutect2
- PRKAR1B | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 349/534 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs770716715; called by mutect2, varscan2
- PRPF31 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 155/411 reads (38%) | catalogued as CD157921; called by muse, mutect2, varscan2
- PRSS35 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 103/133 reads (77%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV104424376; called by muse, mutect2, varscan2
- PTPN22 | c.2128G>A p.E710K (on ENST00000359785 / NM_001193431.2; = p.E655K on NM_012411.5) | Missense Mutation (SNP) | VAF 155/314 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV63086606; called by muse, mutect2, varscan2
- RBP3 | c.3590C>T p.S1197F | Missense Mutation (SNP) | VAF 187/276 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777713935; called by muse, mutect2, varscan2
- RGPD4 | c.1526G>A p.S509N | Missense Mutation (SNP) | VAF 101/353 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100736494; called by muse, mutect2, varscan2
- RIMBP2 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 163/360 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs1225929009; called by muse, mutect2, varscan2
- ROS1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 161/220 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1240410063; called by muse, mutect2, varscan2
- RP1 | c.2869C>T p.P957S | Missense Mutation (SNP) | VAF 111/266 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV55114956; called by muse, mutect2, varscan2
- RRNAD1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 210/442 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs962914867; called by muse, mutect2, varscan2
- RSPH6A | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 111/320 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.398); catalogued as rs145529811; called by muse, mutect2, varscan2
- SCAF1 | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 198/428 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs1334985131, COSV62183034; called by muse, mutect2, varscan2
- SEC14L6 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 166/413 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs760216929; called by muse, mutect2, varscan2
- SI | c.754G>A p.D252N | Missense Mutation (SNP) | VAF 123/297 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.092); catalogued as COSV52272025; called by muse, mutect2, varscan2
- SIRPG | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV99403298; called by muse, mutect2, varscan2
- SLCO1B1 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 114/278 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57008435; called by muse, mutect2, varscan2
- SLIT3 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100265313, COSV60626351; called by muse, mutect2, varscan2
- SLTM | c.1514G>A p.R505K | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377264204; called by muse, mutect2, varscan2
- SOS1 | c.3857C>T p.S1286F | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.085); catalogued as rs374341202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STAT5B | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.075); catalogued as rs1441773574; called by muse, mutect2, varscan2
- TANC2 | c.4234G>A p.E1412K | Missense Mutation (SNP) | VAF 186/417 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.905); catalogued as rs759788253; called by muse, mutect2, varscan2
- TBKBP1 | c.1750C>T p.R584C | Missense Mutation (SNP) | VAF 134/363 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64653742; called by muse, mutect2, varscan2
- TENM2 | c.2767C>T p.P923S (on ENST00000518659 / NM_001122679.2; = p.P691S on NM_001080428.3) | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.573); catalogued as rs745686658, COSV69128457; called by muse, mutect2, varscan2
- TEX13C | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 164/211 reads (78%) | SIFT tolerated (0.83); PolyPhen benign (0.088); catalogued as rs1217207081, COSV50143683; called by muse, mutect2, varscan2
- TFEC | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 93/375 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs768915157, COSV55398167; called by muse, mutect2, varscan2
- TKTL2 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 131/355 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs556498085, COSV54918325; called by muse, mutect2, varscan2
- TLR2 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 135/338 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52605411; called by muse, mutect2, varscan2
- TMEM59 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 75/238 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs1205290002, COSV99329147; called by muse, mutect2, varscan2
- TNFSF11 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 168/417 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53478156; called by muse, mutect2, varscan2
- TPR | c.6143C>T p.S2048F | Missense Mutation (SNP) | VAF 142/317 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs374687100, COSV104427574; called by muse, mutect2, varscan2
- TPTE | c.1510G>A p.E504K (on ENST00000618007 / NM_199261.4; = p.E486K on NM_199259.4) | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.038); catalogued as rs775113189; called by muse, mutect2, varscan2
- TRANK1 | c.2833C>T p.Q945* | Nonsense Mutation (SNP) | VAF 150/407 reads (37%) | catalogued as COSV57168208; called by muse, mutect2, varscan2
- TRAV13-1 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 174/429 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs767763729; called by muse, mutect2
- TTC27 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 74/293 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762694296, COSV58653373; called by muse, mutect2, varscan2
- USH2A | c.6968G>A p.R2323Q | Missense Mutation (SNP) | VAF 112/346 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as rs772014718, COSV56442416; called by muse, mutect2, varscan2
- USP50 | c.389C>A p.P130Q (on ENST00000616326; = p.P121Q on NM_203494.5) | Missense Mutation (SNP) | VAF 127/329 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV101597720; called by muse, mutect2, varscan2
- WNT4 | c.760G>A p.A254T | Missense Mutation (SNP) | VAF 305/619 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0.02); catalogued as rs763133233; called by muse, mutect2, varscan2
- WNT5B | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 157/421 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV100148824; called by muse, mutect2, varscan2
- ZNF112 | c.2669A>C p.K890T (on ENST00000337401 / NM_001083335.2; = p.K884T on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 113/292 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61621210; called by muse, mutect2, varscan2
- ZNF568 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 216/560 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as rs778837491, COSV71278977; called by muse, mutect2
- ZNF626 | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 112/249 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101656994; called by muse, varscan2
- ZNF777 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 361/634 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV99925400; called by muse, mutect2, varscan2
- ZNF792 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 207/492 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV68694290; called by muse, mutect2, varscan2
- ZNF831 | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 217/560 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs748774051, COSV64044676; called by muse, mutect2, varscan2
- AC098582.1 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 178/474 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ADAMTS18 | c.326A>C p.H109P | Missense Mutation (SNP) | VAF 173/400 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADGRL3 | c.4703G>A p.G1568E (on ENST00000506720 / NM_001322402.2; = p.G1457E on NM_015236.6) | Missense Mutation (SNP) | VAF 137/330 reads (42%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- AHCYL2 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 161/250 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALS2CL | c.2452C>T p.L818F | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- AMPD1 | c.2117A>G p.K706R | Missense Mutation (SNP) | VAF 141/414 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, varscan2
- ANKRD33 | c.295G>A p.G99S (on ENST00000340970 / NM_001304459.2; = p.G224S on NM_182608.4) | Missense Mutation (SNP) | VAF 165/415 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANXA7 | c.1081G>A p.E361K (on ENST00000372919 / NM_001320880.2; = p.E339K on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 176/256 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP1B1 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 148/387 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRAF | c.1573T>A p.L525M (on ENST00000288602 / NM_001374244.1; = p.L485M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 178/336 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, varscan2
- BTBD7 | c.3260C>T p.S1087F | Missense Mutation (SNP) | VAF 209/472 reads (44%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- C1QTNF9 | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- C1orf131 | c.106C>A p.L36I | Missense Mutation (SNP) | VAF 33/383 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.103); called by muse, mutect2
- CCDC141 | c.1241T>C p.L414S | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CD14 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 191/460 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CD53 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 97/284 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDK13 | c.2710C>T p.L904F | Missense Mutation (SNP) | VAF 89/343 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CELSR3 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 171/408 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP131 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 83/225 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- CHD7 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 179/464 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CLCA2 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 151/292 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC5A | c.208+1G>A p.X70_splice | Splice Site (SNP) | VAF 147/293 reads (50%) | called by muse, mutect2, varscan2
- COL5A2 | c.1861G>A p.G621S | Missense Mutation (SNP) | VAF 126/242 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL6A3 | c.4892C>T p.S1631L | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- CSNK1D | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 128/348 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CUX2 | c.3781C>T p.P1261S | Missense Mutation (SNP) | VAF 137/328 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- CXCR5 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 76/193 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYP7A1 | c.752A>G p.E251G | Missense Mutation (SNP) | VAF 173/420 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- DEPDC7 | c.151G>A p.E51K (on ENST00000241051 / NM_001077242.2; = p.E42K on NM_139160.2) | Missense Mutation (SNP) | VAF 68/199 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DNAH3 | c.5643A>T p.E1881D | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH7 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 108/219 reads (49%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DOCK5 | c.4963G>C p.G1655R | Missense Mutation (SNP) | VAF 126/511 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DPEP3 | c.467_488del p.L156Pfs*15 | Frame Shift Del (DEL) | VAF 76/234 reads (32%) | called by mutect2, pindel, varscan2
- EFCAB8 | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 107/254 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- ERI1 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 176/299 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- FAM9C | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 106/137 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- FLT4 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 203/499 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FNDC3B | c.314C>T p.S105F | Missense Mutation (SNP) | VAF 101/346 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FOXL1 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 115/286 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- GRM7 | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 136/356 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GSTO2 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 169/241 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HEATR5B | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 110/237 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXB1 | c.667C>T p.H223Y | Missense Mutation (SNP) | VAF 150/416 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS3ST2 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 177/413 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- HSPG2 | c.1244C>T p.S415F | Missense Mutation (SNP) | VAF 157/488 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- IGKV2D-24 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 74/289 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- IL22RA1 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 137/415 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- INTU | c.2718-1G>A p.X906_splice | Splice Site (SNP) | VAF 45/147 reads (31%) | called by muse, mutect2, varscan2
- INTU | c.2718G>A p.G906= | Splice Region (SNP) | VAF 45/148 reads (30%) | called by muse, mutect2, varscan2
- ITPA | c.480T>G p.Y160* | Nonsense Mutation (SNP) | VAF 128/357 reads (36%) | called by muse, mutect2, varscan2
- ITPR2 | c.7447C>T p.L2483F | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- KIF21A | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 379/738 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF21A | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 192/453 reads (42%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.527); called by muse, varscan2
- KIF26A | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 130/330 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- KRT2 | c.1589G>A p.G530E | Missense Mutation (SNP) | VAF 157/393 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- LYPD3 | c.787G>C p.V263L | Missense Mutation (SNP) | VAF 184/469 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEA6 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 229/284 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- MAGED2 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.345); called by muse, mutect2
- MANBA | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MBOAT4 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 181/614 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MC2R | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 113/172 reads (66%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPL16 | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 58/172 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC12 | c.8806G>A p.D2936N (on ENST00000379442; = p.D2793N on NM_001164462.1) | Missense Mutation (SNP) | VAF 165/2594 reads (6%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.975); called by muse, mutect2
- MYL3 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 126/331 reads (38%) | called by muse, mutect2, varscan2
- NASP | c.23C>T p.T8I | Missense Mutation (SNP) | VAF 206/450 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- NCKAP5 | c.3239C>T p.S1080F | Missense Mutation (SNP) | VAF 91/393 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2
- OR10J4 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 146/433 reads (34%) | called by muse, mutect2, varscan2
- OR11H12 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 213/517 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, mutect2, varscan2
- OR2T11 | c.298C>T p.L100F | Missense Mutation (SNP) | VAF 144/447 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR56A5 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 90/280 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- OR5H14 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OSMR | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 163/350 reads (47%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.551); called by muse, varscan2
- P2RY1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 122/279 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- PABPC1L | c.142A>T p.T48S | Missense Mutation (SNP) | VAF 207/499 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PBX1 | c.1106C>T p.S369L | Missense Mutation (SNP) | VAF 132/283 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDHA5 | c.1847G>A p.S616N | Missense Mutation (SNP) | VAF 191/436 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PDCD1 | c.436+1G>A p.X146_splice | Splice Site (SNP) | VAF 127/263 reads (48%) | called by muse, mutect2, varscan2
- PLD1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 107/286 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.09); called by muse, varscan2
- POU2F3 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 62/196 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGS12 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 181/473 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RNF157 | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 163/371 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- RXFP1 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SEC16A | c.2414C>T p.S805F | Missense Mutation (SNP) | VAF 161/422 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- SLC10A4 | c.805T>C p.S269P | Missense Mutation (SNP) | VAF 103/248 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SLC4A1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 146/409 reads (36%) | called by mutect2, pindel, varscan2
- SLC7A13 | c.33_36del p.R11Sfs*33 | Frame Shift Del (DEL) | VAF 90/276 reads (33%) | called by mutect2, pindel, varscan2
- SLC9A3 | c.1172G>A p.W391* | Nonsense Mutation (SNP) | VAF 139/408 reads (34%) | called by muse, mutect2, varscan2
- SMC1B | c.1910A>G p.K637R | Missense Mutation (SNP) | VAF 86/239 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- SOCS1 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 135/358 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SORCS2 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 107/274 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- SPATA31A3 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 95/301 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- SRPRA | c.75C>G p.C25W | Missense Mutation (SNP) | VAF 60/225 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SSU72P4 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 77/389 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- TCAIM | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 122/352 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX55 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 95/270 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- TM9SF4 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 102/323 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TOX2 | c.611G>A p.G204E (on ENST00000358131 / NM_001098798.2; = p.G153E on NM_032883.3) | Missense Mutation (SNP) | VAF 142/400 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- TRPV5 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 335/567 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTC23L | c.839A>G p.Q280R | Missense Mutation (SNP) | VAF 101/255 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- VWA8 | c.5410C>T p.H1804Y | Missense Mutation (SNP) | VAF 107/303 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZBTB8B | c.825C>A p.Y275* | Nonsense Mutation (SNP) | VAF 314/603 reads (52%) | called by muse, mutect2, varscan2
- ZC3H3 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 209/560 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZFX | c.2247dup p.E750* | Frame Shift Ins (INS) | VAF 175/295 reads (59%) | called by mutect2, pindel, varscan2
- ZNF17 | c.1682G>A p.R561K | Missense Mutation (SNP) | VAF 198/440 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF567 | c.1257G>T p.K419N (on ENST00000536254 / NM_001322913.1; = p.K388N on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 171/389 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF775 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 358/634 reads (56%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, varscan2
- ZSWIM2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- AADACL3 | c.714G>A p.R238= | Silent (SNP) | VAF 211/451 reads (47%) | catalogued as rs1056496030; called by muse, mutect2, varscan2
- ABCC4 | c.9C>T p.P3= | Silent (SNP) | VAF 136/353 reads (39%) | called by muse, mutect2, varscan2
- ABCC6 | c.2862C>T p.F954= | Silent (SNP) | VAF 257/594 reads (43%) | called by muse, mutect2, varscan2
- ACSS3 | c.927G>A p.V309= | Silent (SNP) | VAF 99/242 reads (41%) | catalogued as rs1324934923; called by muse, mutect2, varscan2
- ADAMTS10 | c.153G>A p.G51= | Silent (SNP) | VAF 37/483 reads (8%) | catalogued as COSV54352188; called by muse, mutect2
- ADAMTS12 | c.4617C>T p.C1539= | Silent (SNP) | VAF 91/252 reads (36%) | called by muse, mutect2, varscan2
- ADAMTS18 | c.2124C>T p.S708= | Silent (SNP) | VAF 96/243 reads (40%) | catalogued as rs1256468854; called by muse, mutect2, varscan2
- AKAP3 | c.2328C>T p.V776= | Silent (SNP) | VAF 122/322 reads (38%) | called by muse, mutect2, varscan2
- ALOX12B | c.1107C>T p.F369= | Silent (SNP) | VAF 109/322 reads (34%) | catalogued as rs181293386; called by muse, mutect2, varscan2
- AOAH | c.1569C>T p.I523= | Silent (SNP) | VAF 292/518 reads (56%) | catalogued as rs763295900; called by muse, mutect2, varscan2
- ARHGEF10L | c.3549C>T p.L1183= | Silent (SNP) | VAF 326/648 reads (50%) | called by muse, mutect2, varscan2
- ASB7 | c.729G>A p.R243= | Silent (SNP) | VAF 161/406 reads (40%) | called by muse, mutect2, varscan2
- ASZ1 | c.78G>A p.E26= | Silent (SNP) | VAF 266/458 reads (58%) | catalogued as rs768607232; called by muse, mutect2, varscan2
- ATP2B1 | c.1822C>T p.L608= | Silent (SNP) | VAF 63/163 reads (39%) | catalogued as rs374481414; called by muse, mutect2, varscan2
- BRAF | c.1101C>T p.P367= | Silent (SNP) | VAF 193/362 reads (53%) | catalogued as rs745898551; called by muse, mutect2, varscan2
- C1S | c.1890G>A p.G630= | Silent (SNP) | VAF 217/519 reads (42%) | called by muse, mutect2, varscan2
- CAPN14 | c.1617G>A p.Q539= | Silent (SNP) | VAF 67/259 reads (26%) | catalogued as rs1558615824; called by muse, mutect2, varscan2
- CELSR3 | c.2202C>T p.P734= | Silent (SNP) | VAF 174/412 reads (42%) | called by muse, mutect2, varscan2
- CHAT | c.222C>T p.T74= | Silent (SNP) | VAF 157/211 reads (74%) | catalogued as rs767600029; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHD6 | c.3801C>T p.I1267= | Silent (SNP) | VAF 148/337 reads (44%) | catalogued as rs774842452; called by muse, mutect2, varscan2
- CHD7 | c.2787C>T p.I929= | Silent (SNP) | VAF 126/317 reads (40%) | catalogued as rs771367272; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CMYA5 | c.3186G>A p.Q1062= | Silent (SNP) | VAF 161/404 reads (40%) | catalogued as rs754184789; called by muse, mutect2, varscan2
- COL26A1 | c.618G>A p.Q206= (on ENST00000313669 / NM_001278563.3; = p.Q204= on NM_133457.4) | Silent (SNP) | VAF 124/508 reads (24%) | called by muse, mutect2, varscan2
- COL4A2 | c.1110C>T p.A370= | Silent (SNP) | VAF 125/310 reads (40%) | called by muse, mutect2, varscan2
- CUL1 | c.2274G>A p.E758= | Silent (SNP) | VAF 182/323 reads (56%) | catalogued as COSV57386609; called by muse, mutect2, varscan2
- DEF6 | c.327G>A p.G109= | Silent (SNP) | VAF 383/464 reads (83%) | called by muse, mutect2, varscan2
- DENND4B | c.4425G>A p.R1475= | Silent (SNP) | VAF 163/546 reads (30%) | called by muse, mutect2, varscan2
- DOCK9 | c.153C>T p.L51= (on ENST00000376460 / NM_001366676.2; = p.L52= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 111/286 reads (39%) | catalogued as rs764377887; called by muse, mutect2, varscan2
- DPP3 | c.1158C>T p.I386= | Silent (SNP) | VAF 62/180 reads (34%) | catalogued as rs763243569, COSV64756075; called by muse, mutect2, varscan2
- DSG3 | c.1863C>T p.I621= | Silent (SNP) | VAF 143/381 reads (38%) | catalogued as rs753349276, COSV57125446, COSV99934426; called by muse, mutect2, varscan2
- DYRK4 | c.1371G>A p.T457= | Silent (SNP) | VAF 142/339 reads (42%) | catalogued as rs143171709; called by muse, mutect2, varscan2
- DYSF | c.3486G>A p.R1162= | Silent (SNP) | VAF 82/267 reads (31%) | called by muse, mutect2, varscan2
- ECE1 | c.402C>T p.I134= | Silent (SNP) | VAF 181/562 reads (32%) | called by muse, mutect2, varscan2
- EEF1AKNMT | c.1233C>T p.F411= (on ENST00000361735 / NM_015935.5; = p.F325= on NM_014955.3) | Silent (SNP) | VAF 208/413 reads (50%) | catalogued as COSV100675757; called by muse, mutect2, varscan2
- EPB42 | c.282G>A p.V94= (on ENST00000441366 / NM_001114134.2; = p.V124= on NM_000119.3) | Silent (SNP) | VAF 195/270 reads (72%) | called by muse, mutect2, varscan2
- EPHA10 | c.1425G>A p.R475= | Silent (SNP) | VAF 248/466 reads (53%) | called by muse, mutect2, varscan2
- EPHB3 | c.396C>T p.L132= | Silent (SNP) | VAF 157/456 reads (34%) | called by muse, mutect2, varscan2
- EPPK1 | c.681C>T p.A227= | Silent (SNP) | VAF 189/561 reads (34%) | catalogued as COSV73261058; called by muse, mutect2, varscan2
- ETV5 | c.825C>T p.V275= | Silent (SNP) | VAF 169/454 reads (37%) | called by muse, mutect2, varscan2
- FAM186A | c.135C>T p.F45= | Silent (SNP) | VAF 152/364 reads (42%) | catalogued as rs1272437374; called by muse, mutect2, varscan2
- FAM83H | c.1050C>T p.F350= | Silent (SNP) | VAF 210/505 reads (42%) | catalogued as rs1310006292; called by muse, mutect2, varscan2
- FAM9C | c.426G>A p.K142= | Silent (SNP) | VAF 106/137 reads (77%) | catalogued as rs751668951; called by muse, mutect2, varscan2
- FER1L5 | c.187C>T p.L63= | Silent (SNP) | VAF 81/309 reads (26%) | catalogued as rs182799068; called by muse, mutect2, varscan2
- FSCN2 | c.1044C>T p.S348= | Silent (SNP) | VAF 136/346 reads (39%) | called by muse, varscan2
- GABRP | c.1272G>A p.L424= | Silent (SNP) | VAF 85/246 reads (35%) | catalogued as COSV54661470, COSV54665662; called by muse, mutect2, varscan2
- GDAP1 | c.492T>C p.I164= | Silent (SNP) | VAF 114/254 reads (45%) | called by muse, mutect2
- GRIN2B | c.4263C>T p.F1421= | Silent (SNP) | VAF 180/451 reads (40%) | catalogued as rs142577506; called by muse, mutect2, varscan2
- HTRA4 | c.189C>T p.F63= | Silent (SNP) | VAF 195/506 reads (39%) | called by muse, mutect2, varscan2
- ILDR1 | c.843C>T p.I281= (on ENST00000344209 / NM_001199799.2; = p.I237= on NM_175924.4) | Silent (SNP) | VAF 146/369 reads (40%) | catalogued as rs371152020, COSV56548986; called by muse, varscan2
- IQGAP2 | c.2475G>A p.L825= | Silent (SNP) | VAF 142/321 reads (44%) | called by muse, mutect2, varscan2
- IQGAP3 | c.2469C>T p.S823= | Silent (SNP) | VAF 228/427 reads (53%) | called by muse, mutect2, varscan2
- ITGB4 | c.4038C>T p.F1346= | Silent (SNP) | VAF 119/304 reads (39%) | catalogued as COSV99563606; called by muse, mutect2, varscan2
- ITPR2 | c.7446C>A p.L2482= | Silent (SNP) | VAF 114/328 reads (35%) | catalogued as COSV67272377; called by muse, mutect2, varscan2
- KCNA7 | c.1161C>T p.S387= | Silent (SNP) | VAF 146/405 reads (36%) | called by muse, mutect2, varscan2
- KCNJ8 | c.1179G>A p.R393= | Silent (SNP) | VAF 126/326 reads (39%) | called by muse, mutect2, varscan2
- KCNQ2 | c.393C>T p.I131= | Silent (SNP) | VAF 124/287 reads (43%) | catalogued as rs753953009, COSV60432056; called by muse, mutect2, varscan2
- KRT86 | c.1107C>T p.A369= | Silent (SNP) | VAF 204/483 reads (42%) | catalogued as rs376051219; called by muse, mutect2, varscan2
- LBR | c.1533C>T p.F511= | Silent (SNP) | VAF 153/339 reads (45%) | called by muse, mutect2, varscan2
- LGALS4 | c.627C>T p.I209= | Silent (SNP) | VAF 128/325 reads (39%) | called by muse, mutect2, varscan2
- LLGL2 | c.1785C>T p.A595= | Silent (SNP) | VAF 209/528 reads (40%) | catalogued as rs200432063; called by muse, mutect2, varscan2
- MAN1C1 | c.1848G>A p.P616= | Silent (SNP) | VAF 200/428 reads (47%) | catalogued as rs770118162; called by muse, mutect2, varscan2
- MEOX2 | c.288G>A p.Q96= | Silent (SNP) | VAF 212/704 reads (30%) | catalogued as rs753470533, COSV56290051; called by muse, varscan2
- MFN2 | c.1929C>T p.L643= | Silent (SNP) | VAF 242/467 reads (52%) | catalogued as rs767561373; called by muse, mutect2, varscan2
- MRGPRG | c.141C>G p.S47= | Silent (SNP) | VAF 108/349 reads (31%) | called by muse, mutect2, varscan2
- MYO15A | c.27G>A p.K9= | Silent (SNP) | VAF 127/299 reads (42%) | catalogued as rs779915837; called by muse, mutect2, varscan2
- MYO15B | c.8760G>A p.R2920= | Silent (SNP) | VAF 125/334 reads (37%) | catalogued as COSV58644046; called by muse, mutect2, varscan2
- MYO18A | c.75G>A p.K25= | Silent (SNP) | VAF 195/441 reads (44%) | catalogued as rs1356275016; called by muse, mutect2, varscan2
- NCKIPSD | c.1716C>T p.V572= | Silent (SNP) | VAF 115/246 reads (47%) | catalogued as rs1470305713, COSV99583591; called by muse, mutect2, varscan2
- NFRKB | c.2247C>T p.S749= (on ENST00000446488 / NM_001143835.2; = p.S774= on NM_006165.3) | Silent (SNP) | VAF 67/234 reads (29%) | called by muse, mutect2, varscan2
- NOS1 | c.759C>T p.P253= | Silent (SNP) | VAF 123/336 reads (37%) | catalogued as rs771289636, COSV100500407; called by muse, mutect2, varscan2
- NPC1 | c.3558C>T p.R1186= | Silent (SNP) | VAF 139/373 reads (37%) | catalogued as rs141659629, CD149606; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPC1 | c.1989C>T p.I663= | Silent (SNP) | VAF 163/383 reads (43%) | catalogued as rs550696790, COSV52579608, COSV52584183; called by muse, mutect2, varscan2
- NUMB | c.1053C>T p.T351= (on ENST00000355058; = p.T340= on NM_003744.5) | Silent (SNP) | VAF 126/336 reads (38%) | called by muse, mutect2, varscan2
- NUP98 | c.3915T>A p.A1305= (on ENST00000359171 / NM_001365126.1; = p.A1288= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 73/248 reads (29%) | called by muse, mutect2, varscan2
- NYAP2 | c.174G>A p.L58= | Silent (SNP) | VAF 57/226 reads (25%) | called by muse, mutect2, varscan2
- OR52R1 | c.666G>A p.V222= | Silent (SNP) | VAF 120/260 reads (46%) | catalogued as COSV100617665; called by muse, mutect2, varscan2
- OR6S1 | c.510C>T p.F170= | Silent (SNP) | VAF 147/356 reads (41%) | called by muse, mutect2, varscan2
- OSMR | c.1392G>A p.K464= | Silent (SNP) | VAF 82/231 reads (35%) | catalogued as COSV57086988; called by muse, varscan2
- PCDHA11 | c.2364G>A p.Q788= | Silent (SNP) | VAF 143/384 reads (37%) | catalogued as rs782618131; called by muse, mutect2, varscan2
- PLCB4 | c.2811G>A p.K937= | Silent (SNP) | VAF 94/285 reads (33%) | called by muse, mutect2, varscan2
- PLCL1 | c.3033A>G p.A1011= | Silent (SNP) | VAF 62/247 reads (25%) | called by muse, mutect2, varscan2
- PLEKHM2 | c.2272C>T p.L758= | Silent (SNP) | VAF 330/606 reads (54%) | called by muse, mutect2, varscan2
- PMFBP1 | c.957C>T p.C319= | Silent (SNP) | VAF 106/286 reads (37%) | called by muse, mutect2, varscan2
- PRAME | c.1029C>T p.S343= | Silent (SNP) | VAF 184/487 reads (38%) | catalogued as rs888976983, COSV67161744; called by muse, mutect2, varscan2
- PREX2 | c.3711G>A p.R1237= | Silent (SNP) | VAF 94/246 reads (38%) | catalogued as COSV55748771; called by muse, mutect2, varscan2
- RANBP3 | c.759C>T p.D253= (on ENST00000340578 / NM_007322.3; = p.D248= on NM_003624.3) | Silent (SNP) | VAF 136/365 reads (37%) | called by muse, mutect2, varscan2
- RBFOX1 | c.480C>T p.F160= | Silent (SNP) | VAF 100/256 reads (39%) | catalogued as rs919248039, COSV60946947; called by muse, mutect2, varscan2
- RBM46 | c.129G>A p.R43= | Silent (SNP) | VAF 120/272 reads (44%) | catalogued as COSV55982350; called by muse, mutect2, varscan2
- RGPD3 | c.2883G>A p.V961= | Silent (SNP) | VAF 81/457 reads (18%) | catalogued as COSV58743886; called by muse, mutect2, varscan2
- RNASE1 | c.108C>T p.F36= | Silent (SNP) | VAF 145/353 reads (41%) | called by muse, mutect2, varscan2
- RPN1 | c.672C>T p.F224= | Silent (SNP) | VAF 146/369 reads (40%) | catalogued as rs1225072861; called by muse, mutect2, varscan2
- SCN3A | c.1944G>A p.V648= | Silent (SNP) | VAF 93/374 reads (25%) | called by muse, mutect2, varscan2
- SETD1B | c.1758C>T p.L586= | Silent (SNP) | VAF 221/524 reads (42%) | catalogued as rs575380414; called by muse, mutect2, varscan2
- SFMBT2 | c.2220C>T p.L740= | Silent (SNP) | VAF 210/316 reads (66%) | called by muse, mutect2, varscan2
- SFRP2 | c.588G>A p.L196= | Silent (SNP) | VAF 84/209 reads (40%) | catalogued as COSV56837308; called by muse, mutect2, varscan2
- SIGLEC7 | c.1398C>T p.P466= | Silent (SNP) | VAF 91/239 reads (38%) | catalogued as COSV58315477; called by muse, mutect2, varscan2
- SKIV2L | c.1833C>T p.L611= | Silent (SNP) | VAF 445/536 reads (83%) | called by muse, mutect2, varscan2
- SLITRK1 | c.882G>T p.G294= | Silent (SNP) | VAF 58/425 reads (14%) | called by muse, mutect2, varscan2
- SLITRK6 | c.1656C>T p.L552= | Silent (SNP) | VAF 147/382 reads (38%) | catalogued as rs372616753; called by muse, mutect2, varscan2
- SMYD5 | c.975C>T p.S325= | Silent (SNP) | VAF 93/212 reads (44%) | called by muse, mutect2, varscan2
- SPAM1 | c.1167G>A p.R389= | Silent (SNP) | VAF 299/496 reads (60%) | catalogued as COSV56141721; called by muse, mutect2, varscan2
- SPECC1 | c.711G>A p.Q237= | Silent (SNP) | VAF 141/330 reads (43%) | called by muse, mutect2, varscan2
- SPHKAP | c.4344C>T p.S1448= | Silent (SNP) | VAF 78/300 reads (26%) | catalogued as COSV60874056; called by muse, mutect2, varscan2
- SPICE1 | c.1899C>T p.S633= | Silent (SNP) | VAF 169/406 reads (42%) | called by muse, mutect2, varscan2
- SYNPO2 | c.3702C>T p.S1234= | Silent (SNP) | VAF 126/337 reads (37%) | catalogued as COSV61106470; called by muse, mutect2, varscan2
- TAS1R2 | c.474C>T p.L158= | Silent (SNP) | VAF 107/336 reads (32%) | catalogued as rs1349691776, COSV100946303; called by muse, mutect2, varscan2
- TCAF1 | c.2559G>A p.R853= | Silent (SNP) | VAF 37/267 reads (14%) | catalogued as rs1437543635; called by muse, mutect2, varscan2
- TENM4 | c.8154G>A p.R2718= | Silent (SNP) | VAF 121/316 reads (38%) | catalogued as COSV99572234; called by muse, mutect2, varscan2
- TGFB2 | c.189C>T p.V63= | Silent (SNP) | VAF 229/491 reads (47%) | called by muse, mutect2, varscan2
- TGFB2 | c.717C>T p.I239= | Silent (SNP) | VAF 145/300 reads (48%) | catalogued as rs1039969618; called by muse, mutect2, varscan2
- TM9SF4 | c.1119C>T p.S373= | Silent (SNP) | VAF 101/320 reads (32%) | called by muse, mutect2, varscan2
- TMEM132E | c.1326C>T p.V442= (on ENST00000321639; = p.V532= on NM_001304438.2) | Silent (SNP) | VAF 122/339 reads (36%) | called by muse, mutect2, varscan2
- TTN | c.8137C>T p.L2713= (on ENST00000591111; = p.L2667= on NM_003319.4) | Silent (SNP) | VAF 39/206 reads (19%) | called by muse, mutect2, varscan2
- UNC45A | c.2541C>T p.S847= | Silent (SNP) | VAF 128/390 reads (33%) | catalogued as rs868158230; called by muse, mutect2, varscan2
- WFS1 | c.1452T>A p.L484= | Silent (SNP) | VAF 243/582 reads (42%) | called by muse, mutect2
- ZNF284 | c.1140C>T p.F380= | Silent (SNP) | VAF 117/298 reads (39%) | called by muse, mutect2, varscan2
- ZNF579 | c.1369C>T p.L457= | Silent (SNP) | VAF 174/444 reads (39%) | catalogued as rs1191086044; called by muse, mutect2, varscan2
- ZNF592 | c.105G>A p.E35= | Silent (SNP) | VAF 153/387 reads (40%) | catalogued as rs758125949; called by muse, mutect2, varscan2
- ZNF638 | c.2250A>C p.G750= | Silent (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- ZNF716 | c.669C>T p.N223= | Silent (SNP) | VAF 62/622 reads (10%) | called by muse, mutect2
- ARHGEF4 | chr2:130916217 C>T | 5'Flank (SNP) | VAF 86/326 reads (26%) | catalogued as rs1196178883; called by muse, mutect2, varscan2
- FAM98B | chr15:38484519 C>T | 3'Flank (SNP) | VAF 66/103 reads (64%) | called by muse, mutect2, varscan2
- GRIK5 | c.2514+913C>T | Intron (SNP) | VAF 166/449 reads (37%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-28180G>A | Intron (SNP) | VAF 74/215 reads (34%) | catalogued as rs977455984; called by muse, mutect2, varscan2
- KLK3 | c.631-384C>T | Intron (SNP) | VAF 118/306 reads (39%) | catalogued as rs867586023, COSV58102792; called by muse, mutect2, varscan2
- LINC01018 | n.1216A>G | RNA (SNP) | VAF 170/444 reads (38%) | called by muse, mutect2, varscan2
- PHYHIPL | c.*1125G>A | 3'UTR (SNP) | VAF 74/110 reads (67%) | called by muse, mutect2
- TTN | c.10360+1614G>A | Intron (SNP) | VAF 148/287 reads (52%) | catalogued as rs749558211, COSV100594766; called by muse, mutect2, varscan2
- Z99774.2 | chr22:26674897 C>T | 3'Flank (SNP) | VAF 140/362 reads (39%) | called by muse, mutect2, varscan2
